CGCI case HTMCP-02-01-01022 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba660bab-c85a-485e-a158-653fe7ecd583

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Laterality: Bilateral; Classification of tumor: primary; Method of diagnosis: Autopsy; AJCC staging edition: 6th; AJCC clinical N: N1; AJCC clinical M: M1; Prior malignancy: yes; Prior treatment: No; Days to last follow up: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.
2. Neoplasm, NOS: Tissue or organ of origin: Anus, NOS; Classification of tumor: Prior primary.

Follow-up (2 entries)
- Days to follow up: 0 days; Karnofsky performance status: 0.
- Disease response: With Tumor.

Other clinical attributes
- Day 0: Risk factors: Hepatitis C Infection.
- Day 0: Haart treatment indicator: Yes; HIV viral load: 40.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Day 0: Comorbidities: Hepatitis C Infection.
- Nadir CD4 count: 17.
- Risk factors: HIV/AIDS.
- Comorbidities: HIV/AIDS.

Biospecimens (3 samples)
- Sample HTMCP-02-01-01022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-01-01022-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-01-01022-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); Tumor status: With tumor; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1994; Hcv test results: Positive; Haart therapy prior to diagnosis: Yes; History relevant infectious diagnosis: Hepatitis C.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Other method, specify:.
